Somatic mutation profile of tumor specimen TCGA-JY-A6F8-01A (aliquot TCGA-JY-A6F8-01A-11D-A33E-09) from TCGA case TCGA-JY-A6F8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.3 years (20,550 days).
Specimen TCGA-JY-A6F8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9716dd82-94a5-449c-a54c-475c691a4bac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A6F8-10A (Blood Derived Normal), aliquot TCGA-JY-A6F8-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfc5bedf-38ff-403d-8206-23bcfa7c6f60

The open-access MAF lists 115 somatic variants for this specimen: 80 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 32, Nonsense Mutation 5, Frame Shift Del 2, Intron 2, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 34/48 reads (71%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRINP3 | c.1418T>A p.L473H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV66515712; called by muse, mutect2, varscan2
- CASP9 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1324886487; called by muse, mutect2, varscan2
- CDK11B | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.915); catalogued as rs1355162260, COSV52363376; called by muse, mutect2, varscan2
- CIDEB | c.39C>T p.L13= | Splice Region (SNP) | VAF 21/44 reads (48%) | catalogued as rs776821155; called by muse, mutect2, varscan2
- CRHR1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs375123636; called by muse, mutect2, varscan2
- DMXL2 | c.4042C>T p.H1348Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99196173; called by muse, mutect2, varscan2
- DNAH10 | c.10291C>T p.R3431C (on ENST00000409039; = p.R3370C on NM_207437.3) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369076491; called by muse, mutect2, varscan2
- DNM1 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs757501966, COSV57854034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNTT | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs767993308, COSV100960624; called by muse, mutect2, varscan2
- FAM47C | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV63730944; called by muse, mutect2, varscan2
- FBF1 | c.2716G>A p.E906K (on ENST00000586717; = p.E920K on NM_001319193.1) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs573986983; called by muse, mutect2, varscan2
- IRX6 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs774614853, COSV51860802; called by muse, mutect2, varscan2
- KCNH8 | c.433A>G p.K145E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs1393242746; called by muse, mutect2, varscan2
- KIAA0513 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs759199789; called by muse, mutect2, varscan2
- LDLRAD1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as rs544114152; called by muse, mutect2, varscan2
- LPA | c.5519G>T p.R1840M | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1163245605, COSV60302671; called by muse, mutect2, varscan2
- MAP3K1 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs756966178, COSV68127702; called by muse, mutect2, varscan2
- MMUT | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs528689712; called by muse, mutect2, varscan2
- NCL | c.2068_2079del p.F690_G693del | In Frame Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs758701047; called by mutect2, varscan2
- NOVA2 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1027936364; called by muse, mutect2, varscan2
- NRG3 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.186); catalogued as COSV64545740; called by muse, mutect2, varscan2
- OR6K3 | c.581T>C p.F194S (on ENST00000368146; = p.F178S on NM_001005327.2) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63745297; called by muse, varscan2
- OR6N1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as rs150263738, COSV58648929; called by muse, mutect2, varscan2
- P3H2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537288155, COSV60024619; called by muse, mutect2, varscan2
- PKHD1L1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV65737606; called by muse, mutect2
- ROBO2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); catalogued as rs199705591, COSV59939072; ClinVar: likely benign; called by muse, mutect2, varscan2
- RTL5 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.166); catalogued as rs373524278, COSV101029985, COSV65453092; called by muse, mutect2, varscan2
- SDK1 | c.3809G>A p.R1270Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs376608111; called by muse, mutect2, varscan2
- SLC9C2 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs535826422; called by muse, varscan2
- SORCS1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs1428401566, COSV53859229, COSV53908576; called by muse, mutect2, varscan2
- TECTA | c.6026T>C p.I2009T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM115255; called by muse, mutect2, varscan2
- TEKT4 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as rs372239927; called by muse, mutect2, varscan2
- TTN | c.50987G>A p.R16996H (on ENST00000591111; = p.R9572H on NM_003319.4) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | PolyPhen probably damaging (0.998); catalogued as rs758627195, COSV100613682, COSV100630189; ClinVar: uncertain significance; called by muse, varscan2
- VBP1 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1557309025; called by muse, mutect2, varscan2
- ZNF765 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs774451077; called by muse, mutect2, varscan2
- ADCK5 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- ANGPT1 | c.1490A>T p.D497V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ATF7 | c.997C>T p.R333* (on ENST00000548446 / NM_001366555.2; = p.R322* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- BAZ2A | c.2659C>G p.L887V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- BBS12 | c.1787A>G p.Q596R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C8A | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- C8B | c.1503T>G p.S501R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CAMTA2 | c.3464G>A p.R1155H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC171 | c.3521C>T p.T1174I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.344); called by mutect2, varscan2
- CCDC80 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA4 | c.75C>T p.R25= | Splice Region (SNP) | VAF 16/17 reads (94%) | called by muse, mutect2, varscan2
- CSMD3 | c.7156A>C p.S2386R (on ENST00000297405 / NM_001363185.1; = p.S2282R on NM_052900.3) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2
- DYNC2H1 | c.4696C>G p.Q1566E | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERC2 | c.2147G>C p.R716P | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FAT3 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FCN1 | c.441C>G p.D147E | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FCSK | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FRMD7 | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GLI3 | c.2565C>A p.S855R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTT | c.3533dup p.S1179Kfs*27 | Frame Shift Ins (INS) | VAF 11/96 reads (11%) | called by mutect2, pindel, varscan2
- IAH1 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGKV1-5 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- KCNQ3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- KRT72 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- MAN1A1 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MBOAT1 | c.147G>C p.W49C | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- MRTFB | c.129dup p.P44Tfs*40 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- MTMR6 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NFATC1 | c.2204C>G p.A735G | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.44); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PLCE1 | c.6514G>A p.A2172T | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RACK1 | c.162T>G p.I54M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- RAP1GDS1 | c.1177A>G p.I393V (on ENST00000408927 / NM_001100427.2; = p.I394V on NM_021159.5) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RIMS1 | c.3122T>G p.L1041R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SCYL1 | c.1967_1974del p.A656Gfs*18 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- SH3GLB1 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3295G>T p.V1099L | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC52A3 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTF2 | c.2735G>T p.S912I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TUBA3C | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- YTHDF2 | c.1676_1677del p.H559Lfs*2 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2
- ZC3H13 | c.2916G>T p.E972D | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZCCHC14 | c.2069G>A p.S690N (on ENST00000268616; = p.S827N on NM_015144.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ZNF230 | c.917A>T p.K306I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF680 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGAP1 | c.786C>T p.A262= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs137978600; called by muse, mutect2, varscan2
- COL2A1 | c.501C>A p.P167= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as rs768549401, COSV100476113; called by muse, mutect2, varscan2
- COL5A1 | c.5205C>T p.S1735= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs747118500, COSV65666805; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPZ | c.1560C>T p.N520= (on ENST00000360986 / NM_001014447.3; = p.N509= on NM_003652.3) | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs111747511; called by muse, mutect2, varscan2
- CSMD1 | c.6504G>T p.P2168= (on ENST00000520002; = p.P2167= on NM_033225.6) | Silent (SNP) | VAF 110/126 reads (87%) | catalogued as COSV59289747, COSV59322456; called by muse, mutect2, varscan2
- CTAGE1 | c.1287A>G p.A429= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- CTU2 | c.463C>T p.L155= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- DAGLA | c.2559G>A p.T853= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV57197961; called by muse, mutect2
- DCC | c.1191T>C p.F397= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100499293; called by muse, mutect2, varscan2
- FN1 | c.6066C>T p.F2022= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs776023777, COSV100118486; called by muse, mutect2, varscan2
- GALNT8 | c.195G>A p.V65= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs373981442; called by muse, mutect2, varscan2
- JPH4 | c.1575C>A p.P525= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- LNX1 | c.708C>T p.S236= (on ENST00000263925 / NM_001126328.3; = p.S140= on NM_032622.2) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs143497847; called by muse, mutect2, varscan2
- LRIT3 | c.1404G>A p.K468= | Silent (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.951A>G p.K317= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV63040811; called by muse, mutect2, varscan2
- MAP3K19 | c.384G>A p.T128= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs748788183, COSV100208263, COSV59642610; called by muse, mutect2, varscan2
- MYC | c.387C>T p.I129= (on ENST00000377970; = p.I144= on NM_002467.6) | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- NALCN | c.3792G>A p.S1264= | Silent (SNP) | VAF 49/66 reads (74%) | catalogued as rs150385138; called by muse, mutect2, varscan2
- PAQR6 | c.378C>T p.Y126= (on ENST00000292291 / NM_001272108.2; = p.Y20= on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- PFKFB2 | c.1251C>T p.L417= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- PHYKPL | c.951C>T p.C317= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs755182524; called by muse, mutect2, varscan2
- PLTP | c.510G>A p.T170= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs926077509; called by muse, mutect2, varscan2
- POLR1A | c.2070G>A p.T690= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs545753325, COSV99807647; called by muse, mutect2, varscan2
- RYR3 | c.6453G>A p.A2151= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs770216543, COSV101211891, COSV66787409; called by muse, mutect2, varscan2
- SALL1 | c.321A>G p.Q107= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV51755249; called by muse, varscan2
- SLC22A12 | c.576C>T p.F192= | Silent (SNP) | VAF 36/46 reads (78%) | catalogued as rs747260736, COSV60571326; called by muse, mutect2, varscan2
- SNAPC4 | c.4182G>A p.S1394= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as rs533786159; called by muse, mutect2, varscan2
- SORCS1 | c.678G>A p.L226= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- SYDE2 | c.1986T>C p.A662= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1340248606; called by muse, mutect2, varscan2
- VIPR1 | c.351G>A p.P117= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs757213503, COSV57296594; called by muse, mutect2, varscan2
- WDFY3 | c.3378G>A p.V1126= | Silent (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2
- XIRP2 | c.3678A>G p.E1226= (on ENST00000628543; = p.E1401= on NM_152381.6) | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1268319895, COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2, varscan2
- HUWE1 | c.1490-759G>T | Intron (SNP) | VAF 28/33 reads (85%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5523C>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs775574237, COSV56223098; called by mutect2, varscan2
- TUBB7P | n.1193C>T | RNA (SNP) | VAF 60/112 reads (54%) | catalogued as rs1277965801; called by muse, mutect2, varscan2
